Somatic mutation profile of tumor specimen TCGA-86-8668-01A (aliquot TCGA-86-8668-01A-11D-2393-08) from TCGA case TCGA-86-8668, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchio-alveolar carcinoma, mucinous; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 61.3 years (22,383 days).
Specimen TCGA-86-8668-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1da0bfb1-2d97-46f0-8936-5f994af9c44d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-8668-10A (Blood Derived Normal), aliquot TCGA-86-8668-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6eba534-2f5c-4001-a45f-aedea1b56a81

The open-access MAF lists 33 somatic variants for this specimen: 26 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 22, Silent 7, Frame Shift Del 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 27/182 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- BSDC1 | c.1093T>A p.L365I | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs532220214, COSV100344731; called by muse, mutect2, varscan2
- FGFR4 | c.611A>C p.H204P | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV99449766; called by muse, mutect2
- HOXA3 | c.738C>A p.Y246* | Nonsense Mutation (SNP) | VAF 35/179 reads (20%) | catalogued as COSV100415457; called by muse, mutect2, varscan2
- KBTBD8 | c.582C>A p.D194E | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as rs1017890140, COSV99805650; called by muse, mutect2, varscan2
- KCNS3 | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100411210; called by muse, mutect2
- LRRC66 | c.1946T>A p.L649H | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV100602953; called by muse, mutect2, varscan2
- NPC1L1 | c.2864A>G p.D955G | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1380412403, COSV99208896; called by muse, mutect2, varscan2
- PDE6C | c.144G>T p.M48I | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs566501091, COSV101008742; called by muse, mutect2, varscan2
- PRSS16 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs777043243, COSV100041729; called by muse, mutect2, varscan2
- RFC1 | c.1514G>A p.R505K | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100567661, COSV62901019; called by muse, mutect2
- SCN8A | c.2707G>A p.E903K | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.676); catalogued as COSV100633785, COSV61981172; called by muse, mutect2, varscan2
- SDF2 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778547628, COSV99897892; called by muse, mutect2, varscan2
- SOX11 | c.352T>A p.Y118N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100431074; called by muse, mutect2, varscan2
- ST13 | c.184A>T p.S62C | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV53422926, COSV99344156; called by muse, mutect2, varscan2
- STAMBP | c.86A>C p.E29A | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.382); catalogued as COSV100277688; called by muse, mutect2, varscan2
- TBX6 | c.754T>A p.Y252N | Missense Mutation (SNP) | VAF 107/314 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99661642; called by muse, mutect2, varscan2
- TENM2 | c.5941G>A p.G1981S (on ENST00000518659 / NM_001122679.2; = p.G1742S on NM_001080428.3) | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as rs774907725, COSV101318641; called by muse, mutect2, varscan2
- TMEM225 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs114104204, COSV66693548; called by muse, mutect2, varscan2
- TMEM43 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1430520295, COSV99542279; called by muse, mutect2
- USP51 | c.969G>C p.Q323H | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.805); catalogued as COSV101540663; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1756C>T p.R586W | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.762); catalogued as rs1476558388, COSV60158115; called by muse, mutect2, varscan2
- ZNF570 | c.1384C>T p.R462* | Nonsense Mutation (SNP) | VAF 18/114 reads (16%) | catalogued as rs761712888, COSV100356166; called by muse, mutect2, varscan2
- C4BPA | c.43del p.R15Gfs*22 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | called by mutect2, varscan2
- RASL10B | c.520C>A p.L174I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- ZNF468 | c.582del p.N194Kfs*17 | Frame Shift Del (DEL) | VAF 42/180 reads (23%) | called by mutect2, pindel, varscan2
- ADSS1 | c.888C>T p.G296= | Silent (SNP) | VAF 16/156 reads (10%) | catalogued as rs553526202, COSV58274568; ClinVar: likely benign; called by muse, mutect2
- ENGASE | c.699G>A p.L233= | Silent (SNP) | VAF 5/80 reads (6%) | catalogued as COSV100285779; called by muse, mutect2
- FAM107A | c.381C>G p.V127= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as rs372110203; called by muse, mutect2, varscan2
- LRP1B | c.7383T>C p.N2461= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as rs373513777; called by muse, mutect2, varscan2
- SDK1 | c.1479C>T p.D493= | Silent (SNP) | VAF 27/174 reads (16%) | catalogued as rs149234557; called by muse, mutect2, varscan2
- TACR3 | c.312C>G p.L104= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV100510418; called by muse, mutect2, varscan2
- TNFAIP1 | c.6G>A p.S2= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as rs782191222, COSV99880300, COSV99880469; called by muse, mutect2
